Gene-level copy-number profile of tumor specimen TCGA-19-2624-01A from TCGA case TCGA-19-2624, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.7 years (18,891 days).
Specimen TCGA-19-2624-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.dfb04e43-26eb-43b8-ad51-b4ab596c781a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-19-2624-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3a518e56-7f35-4d3d-ba86-3119de319233

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,001; copy number 2: 51,583; copy number 3: 3,156; copy number 23: 23; copy number 24: 19; copy number 26: 8; copy number 27: 3; copy number 28: 10; copy number 30: 10; copy number 31: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-19-2624-01A-01D-0911-01): tumor purity 0.94, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 75 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–55,713,252, 17 genes, copy number 24: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr12:57,674,665–57,896,846, 23 genes, copy number 23: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.
- chr12:57,977,965–57,984,761, 2 genes, copy number 24: RN7SKP65, AC084033.2.
- chr12:58,244,378–58,395,138, 2 genes, copy number 31: RPL21P103, AC025578.1.
- chr12:62,643,994–62,935,150, 1 gene, copy number 28 (within-gene range 1–28): PPM1H.
- chr12:62,755,227–63,151,201, 9 genes, copy number 28 (within-gene range 1–28): GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A.
- chr12:64,709,458–64,990,646, 7 genes, copy number 26 (within-gene range 1–26): AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389.
- chr12:64,939,023–64,939,117, 1 gene, copy number 26: RNU6ATAC42P.
- chr12:66,950,754–67,132,205, 3 genes, copy number 27: AC073530.1, AC073530.2, RAB11AP2.
- chr12:68,674,371–68,850,686, 10 genes, copy number 30: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.

Autosomal genes at a single copy (total copy number 1): 2,620. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
